CCDI case PBBYWI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/962bd687-4df3-4f39-b11b-c6919da8a098

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.6 years (6,056 days).

Biospecimens (3 samples)
- Sample 0DL0IX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL0J6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL0JY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
